Somatic mutation profile of tumor specimen MP2PRT-PASYYC-TMP1-A (aliquot MP2PRT-PASYYC-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASYYC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,155 days).
Specimen MP2PRT-PASYYC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1258f343-7391-4041-955e-e92940944f70.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASYYC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASYYC-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b9c7598-245d-4f3e-b29b-c7145fdb427c

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 43/242 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DENND2B | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 138/479 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1441658809, COSV58208423; called by muse, mutect2, varscan2
- ENTPD3 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140869368; called by muse, mutect2, varscan2
- FRAS1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773283272, COSV53592068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TICAM1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs762981932; called by muse, mutect2, varscan2
- COL6A6 | c.2951C>A p.A984D | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP2U1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 27/750 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IFNLR1 | c.1484A>G p.D495G | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PQBP1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 150/677 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCG3 | c.1349_1350insGCCCT p.G451Pfs*2 | Frame Shift Ins (INS) | VAF 51/298 reads (17%) | called by mutect2, pindel*, varscan2
- SLC34A2 | c.1595A>G p.Y532C | Missense Mutation (SNP) | VAF 105/585 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UBR4 | c.10988G>A p.C3663Y | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATP10D | c.2391C>T p.G797= | Silent (SNP) | VAF 84/406 reads (21%) | catalogued as rs756637902, COSV56705535; called by muse, mutect2, varscan2
- PTPRZ1 | c.2409C>T p.V803= | Silent (SNP) | VAF 20/419 reads (5%) | catalogued as rs1469171569; called by muse, mutect2
- ZNF133 | c.1146C>T p.Y382= (on ENST00000316358 / NM_001352454.2; = p.Y381= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 116/387 reads (30%) | catalogued as rs539564855; called by muse, mutect2, varscan2
- MLIP | c.613-11862G>A | Intron (SNP) | VAF 79/550 reads (14%) | catalogued as rs918317474; called by muse, mutect2, varscan2
